Somatic mutation profile of tumor specimen TARGET-20-PAPZJT-40A (aliquot TARGET-20-PAPZJT-40A-01D) from TARGET case TARGET-20-PAPZJT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.8 years (277 days).
Specimen TARGET-20-PAPZJT-40A: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bc2b29a-fcb6-43ae-b155-4feffa013fca.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPZJT-14A (Bone Marrow Normal), aliquot TARGET-20-PAPZJT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/218d24ad-d129-457e-b274-6126bfe0f3a6

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs587782868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.2059A>G p.I687V | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150891608; called by muse, mutect2
- GAREM1 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs750510616; called by muse, mutect2, varscan2
- MKI67 | c.1908T>A p.H636Q | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs146178090; called by muse, mutect2, varscan2
- PCLO | c.5113A>G p.T1705A | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs760807428; called by muse, mutect2, varscan2
- CARD11 | c.2316G>A p.S772= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs763092414, COSV100829067, COSV62754031; called by muse, mutect2, varscan2
- FLNB | c.2550A>C p.A850= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- LAMB2 | c.4173C>T p.G1391= | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- MKI67 | c.9009T>C p.D3003= | Silent (SNP) | VAF 64/132 reads (48%) | catalogued as rs1050688874; called by muse, mutect2, varscan2
- PTPRA | c.126A>G p.P42= | Silent (SNP) | VAF 69/146 reads (47%) | catalogued as rs374149621; called by muse, mutect2, varscan2
- ASB1 | c.*262G>C | 3'UTR (SNP) | VAF 81/155 reads (52%) | catalogued as rs543032542; called by muse, mutect2, varscan2
- CSF3R | chr1:36482916 C>T | 5'Flank (SNP) | VAF 24/50 reads (48%) | catalogued as rs537330379; called by muse, mutect2, varscan2
